Somatic mutation profile of tumor specimen TCGA-AA-A022-01A (aliquot TCGA-AA-A022-01A-21W-A096-10) from TCGA case TCGA-AA-A022, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage II; Age at diagnosis: 88.8 years (32,446 days).
Specimen TCGA-AA-A022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dc5f11c-a054-4ccf-bd07-2a1a99aa4fc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A022-11A (Solid Tissue Normal), aliquot TCGA-AA-A022-11A-11D-A17O-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef0b166e-dfc8-44eb-9f91-22f1036c9763

The open-access MAF lists 1,565 somatic variants for this specimen: 1,171 protein-altering or splice-affecting, 360 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 802, Silent 360, Frame Shift Del 231, Nonsense Mutation 49, Frame Shift Ins 48, Splice Site 20, RNA 14, Intron 12, Splice Region 11, In Frame Del 10, 3'UTR 3, 5'UTR 3.

Variants (750 of 1,565; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/289 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CEP290 | c.6869dup p.N2290Kfs*6 | Frame Shift Ins (INS) | VAF 558/1343 reads (42%) | catalogued as rs587783017; ClinVar: pathogenic; called by mutect2, varscan2
- F5 | c.6304C>T p.R2102C | Missense Mutation (SNP) | VAF 242/630 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs118203910, CM030037, COSV63121893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1973G>A p.R658Q (on ENST00000281708 / NM_001349798.2; = p.R578Q on NM_018315.5) | Missense Mutation (SNP) | VAF 129/441 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs759610249, COSV55905466; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by pindel, varscan2
- KLHL3 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs199469633, CM120723, COSV59050916; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.10653dup p.A3552Sfs*4 | Frame Shift Ins (INS) | VAF 36/97 reads (37%) | catalogued as rs763440821; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NLRP7 | c.2471+1G>A p.X824_splice (on ENST00000340844 / NM_206828.3; = p.X796_splice on NM_139176.3) | Splice Site (SNP) | VAF 36/101 reads (36%) | catalogued as rs104895505, CS061310, COSV60178990; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SCN1A | c.4339-1G>A p.X1447_splice (on ENST00000303395 / NM_001202435.3; = p.X1436_splice on NM_006920.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/267 reads (7%) | catalogued as rs1553522517, CS031804, COSV100319173, COSV100320730; ClinVar: pathogenic; called by muse, mutect2
- SCN5A | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.41); catalogued as rs761117662, COSV61118422; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SF3B4 | c.1147del p.H383Mfs*75 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs387907186, CD123383; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, varscan2
- TRPS1 | c.2755G>A p.A919T (on ENST00000220888 / NM_001330599.2; = p.A932T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518972, CM010488, COSV99628169; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs750440854, COSV99966581; called by muse, varscan2
- AAAS | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs902369500, COSV99266801; called by muse, mutect2, varscan2
- AADACL2 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.616); catalogued as rs764675842, COSV100735657; called by muse, mutect2
- AADACL2 | c.824G>T p.R275I | Missense Mutation (SNP) | VAF 136/352 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.309); catalogued as COSV100735658; called by muse, mutect2, varscan2
- ABCA13 | c.3692T>C p.L1231P | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101329913; called by muse, mutect2, varscan2
- ABCA9 | c.3498del p.F1166Lfs*5 | Frame Shift Del (DEL) | VAF 162/501 reads (32%) | catalogued as rs1177267466; called by mutect2, pindel, varscan2
- ABCC4 | c.2689C>T p.R897W | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769663620, COSV65317475; called by muse, mutect2, varscan2
- ABCC6 | c.4124T>C p.L1375P | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228006; called by muse, mutect2, varscan2
- ABHD12B | c.556C>T p.P186S (on ENST00000337334 / NM_001206673.2; = p.P109S on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV100485535; called by muse, mutect2, varscan2
- ABL1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.925); catalogued as rs766513552, COSV100583401; called by muse, mutect2, varscan2
- AC004922.1 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53162608; called by muse, mutect2, varscan2
- ACE2 | c.1481A>G p.D494G | Missense Mutation (SNP) | VAF 58/584 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV99382516; called by muse, mutect2
- ACKR3 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs143911695; called by muse, varscan2
- ACMSD | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs372245923; called by muse, mutect2, varscan2
- ACOT12 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 69/199 reads (35%) | catalogued as COSV100296706; called by muse, mutect2, varscan2
- ACSL1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV99860312; called by muse, mutect2, varscan2
- ACSS2 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 394/1239 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774600970, COSV53626839; called by muse, mutect2, varscan2
- ACSS3 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 132/478 reads (28%) | catalogued as rs774448807, COSV99698242; called by muse, varscan2
- ACTG2 | c.85del p.R29Gfs*16 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as rs751325833; called by mutect2, pindel, varscan2
- ACTR1B | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780700382, COSV56705245; called by muse, mutect2, varscan2
- ACVR1B | c.1346A>T p.D449V | Missense Mutation (SNP) | VAF 131/268 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV99231242; called by muse, mutect2, varscan2
- ADAMTS20 | c.4570C>T p.R1524* | Nonsense Mutation (SNP) | VAF 292/524 reads (56%) | catalogued as rs186549011, COSV101238834; called by muse, mutect2, varscan2
- ADAMTS5 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53184176, COSV99536978; called by muse, mutect2, varscan2
- ADCY2 | c.2465G>T p.R822I | Missense Mutation (SNP) | VAF 133/482 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV57903018; called by muse, mutect2, varscan2
- ADCY5 | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs759519156, COSV59199318; called by muse, mutect2, varscan2
- ADGRA3 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1404660498, COSV99292871; called by muse, mutect2, varscan2
- ADGRG6 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as rs184591267; called by muse, mutect2, varscan2
- ADIPOQ | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 343/988 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100292078; called by muse, mutect2, varscan2
- AGAP1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328244428, COSV58324497, COSV58333147; called by muse, mutect2, varscan2
- AGK | c.1132-1G>T p.X378_splice | Splice Site (SNP) | VAF 53/202 reads (26%) | catalogued as COSV100814521; called by muse, mutect2, varscan2
- AGO1 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 119/401 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV64595103; called by muse, mutect2, varscan2
- AGO1 | c.2435G>A p.R812Q | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867363147, COSV100940747; called by muse, mutect2
- AGO3 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.566); catalogued as COSV99867950; called by muse, mutect2, varscan2
- AGTPBP1 | c.3237del p.K1079Nfs*10 (on ENST00000357081 / NM_001330701.2; = p.K1039Nfs*10 on NM_015239.2) | Frame Shift Del (DEL) | VAF 162/489 reads (33%) | catalogued as COSV61278568; called by mutect2, pindel, varscan2
- AHNAK | c.10831A>G p.S3611G | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.961); catalogued as rs773658459, COSV99945433; called by muse, mutect2, varscan2
- AK5 | c.1620+2C>T p.X540_splice (on ENST00000354567 / NM_174858.3; = p.X514_splice on NM_012093.4) | Splice Site (SNP) | VAF 23/68 reads (34%) | catalogued as rs770347979, COSV100642358; called by muse, varscan2
- AL358113.1 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.121); catalogued as rs1037430967, COSV61957022; called by muse, mutect2, varscan2
- ALAS1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs766975956, COSV100050196; called by muse, mutect2, varscan2
- ALDH1A1 | c.569T>A p.V190E | Missense Mutation (SNP) | VAF 399/674 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99920992; called by muse, mutect2, varscan2
- ALDH2 | c.414T>G p.D138E | Missense Mutation (SNP) | VAF 85/357 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.632); catalogued as COSV55669841; called by muse, mutect2, varscan2
- ALOX12B | c.1654G>T p.G552C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201448391, COSV100046611; called by muse, mutect2, varscan2
- AMPD2 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs751131036, COSV99857322; called by muse, mutect2, varscan2
- ANGPT2 | c.445-1G>T p.X149_splice | Splice Site (SNP) | VAF 193/585 reads (33%) | catalogued as COSV100290584; called by muse, mutect2, varscan2
- ANGPTL7 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771394500, COSV63880241; called by muse, mutect2, varscan2
- ANK2 | c.5786C>T p.S1929L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs779278730, COSV52173219, COSV52192251; called by muse, mutect2, varscan2
- ANKRD10 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs755781873, COSV99941018; called by muse, mutect2, varscan2
- ANKRD27 | c.3086T>C p.V1029A | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100042521; called by muse, mutect2, varscan2
- ANKRD35 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.354); catalogued as COSV100841622; called by muse, mutect2, varscan2
- ANKRD50 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs376403231, COSV72385179; called by muse, mutect2, varscan2
- ANO10 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs375470443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP1G2 | c.1345del p.A449Pfs*84 | Frame Shift Del (DEL) | VAF 42/98 reads (43%) | catalogued as rs749982998; called by mutect2, varscan2
- APOB | c.9406C>T p.R3136C | Missense Mutation (SNP) | VAF 124/398 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs72653102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.5063G>T p.G1688V | Missense Mutation (SNP) | VAF 140/433 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99263404; called by muse, mutect2, varscan2
- ARFGEF3 | c.6001C>T p.R2001W | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs182084247, COSV99292209; called by muse, mutect2, varscan2
- ARHGAP32 | c.2105G>A p.R702H (on ENST00000310343 / NM_001378025.1; = p.R353H on NM_014715.4) | Missense Mutation (SNP) | VAF 103/317 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs149060649; called by muse, mutect2, varscan2
- ARHGEF18 | c.1129G>T p.A377S (on ENST00000359920 / NM_001130955.2; = p.A273S on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as rs756709811, COSV100148924; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs749402223; called by mutect2, varscan2
- ARHGEF7 | c.1966C>T p.R656W (on ENST00000375741 / NM_001113511.2; = p.R478W on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866152255, COSV54538783, COSV54548582; called by muse, mutect2, varscan2
- ARMC3 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1364429442, COSV99957397; called by muse, mutect2, varscan2
- ARMCX2 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 425/672 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as COSV100168013, COSV57530761; called by muse, mutect2, varscan2
- ASCC3 | c.6561G>T p.Q2187H | Missense Mutation (SNP) | VAF 253/700 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV100976193; called by muse, mutect2, varscan2
- ASPHD2 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747070863, COSV99313098, COSV99313499; called by muse, mutect2, varscan2
- ASXL2 | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 74/1446 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.053); catalogued as rs374285356, COSV99710118; called by muse, mutect2
- ATCAY | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100008445, COSV56658323, COSV56659582; called by muse, mutect2, varscan2
- ATM | c.3070G>A p.A1024T | Missense Mutation (SNP) | VAF 172/591 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs1397754737, COSV99587113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP12A | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 383/1031 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV99516950; called by muse, mutect2, varscan2
- ATP13A1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99365562; called by muse, mutect2, varscan2
- ATP13A1 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99365565; called by muse, mutect2, varscan2
- ATP13A2 | c.68C>G p.T23R | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV100453879; called by muse, mutect2, varscan2
- ATP7A | c.1789G>A p.V597M | Missense Mutation (SNP) | VAF 204/298 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781959472, COSV58451117; ClinVar: uncertain significance; called by muse, varscan2
- ATPSCKMT | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs559270054, COSV54726807, COSV99725982; called by muse, mutect2, varscan2
- ATRNL1 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV100744074; called by muse, mutect2, varscan2
- AVPR1A | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV100146795, COSV54546135; called by muse, mutect2, varscan2
- AXIN2 | c.2062del p.L688* | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as CM067349, COSV61056020; called by mutect2, varscan2
- B4GALT6 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 89/178 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs901456078, COSV52704419; called by muse, varscan2
- BAZ2A | c.5413A>G p.I1805V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV51640895; called by muse, mutect2, varscan2
- BAZ2A | c.1025G>A p.C342Y | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51635735, COSV51640909; called by muse, mutect2
- BCAS2 | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 177/484 reads (37%) | catalogued as COSV101058482; called by muse, mutect2, varscan2
- BCOR | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 36/52 reads (69%) | catalogued as COSV60714969; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 34/53 reads (64%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEND3 | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64680264; called by muse, mutect2, varscan2
- BICC1 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 112/354 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100874693; called by muse, mutect2, varscan2
- BICC1 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs775676179, COSV54066020; called by muse, mutect2, varscan2
- BIRC2 | c.62T>C p.I21T | Missense Mutation (SNP) | VAF 153/416 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99926503; called by muse, mutect2, varscan2
- BMX | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 259/371 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs774703027, COSV100564259, COSV100564556; called by mutect2, varscan2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 44/162 reads (27%) | catalogued as rs751941533; called by pindel, varscan2
- BRAF | c.1328dup p.A444Cfs*9 (on ENST00000288602 / NM_001374244.1; = p.A404Cfs*9 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 34/134 reads (25%) | catalogued as rs777474487; called by mutect2, varscan2
- BRINP1 | c.2048G>A p.G683D | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV99774317; called by muse, mutect2, varscan2
- BRINP1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99059353, COSV99774319; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BSX | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1466704692, COSV58006322; called by muse, mutect2, varscan2
- BTBD3 | c.1244C>G p.S415C | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54779135, COSV99655599; called by muse, mutect2, varscan2
- C11orf24 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756449465, COSV100422461, COSV100422672; called by muse, mutect2, varscan2
- C16orf46 | c.743G>A p.C248Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV100215082; called by muse, mutect2, varscan2
- C16orf78 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54556399; called by muse, mutect2, varscan2
- C16orf78 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1252336191, COSV54555752; called by muse, mutect2, varscan2
- C17orf58 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.249); catalogued as COSV100558699; called by muse, mutect2, varscan2
- C19orf57 | c.1942del p.L648Cfs*25 (on ENST00000586783 / NM_001345843.1; = p.L617Cfs*25 on NM_024323.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs1270763461; called by mutect2, pindel, varscan2
- C1orf159 | c.455C>T p.T152M (on ENST00000379339 / NM_001330306.2; = p.T116M on NM_017891.5) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772422279, COSV99618119; called by muse, mutect2, varscan2
- C4orf50 | c.661C>T p.R221C (on ENST00000324058; = p.R1453C on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201256752, COSV60689457; called by muse, mutect2, varscan2
- C8B | c.1629del p.I544Lfs*51 | Frame Shift Del (DEL) | VAF 78/331 reads (24%) | catalogued as rs762770227; called by mutect2, pindel, varscan2
- CA2 | c.440dup p.L147Ffs*7 | Frame Shift Ins (INS) | VAF 89/263 reads (34%) | catalogued as rs763603775; called by mutect2, varscan2
- CAAP1 | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV61700397; called by mutect2, varscan2
- CABLES1 | c.938C>G p.S313* (on ENST00000256925 / NM_001100619.2; = p.S48* on NM_138375.2) | Nonsense Mutation (SNP) | VAF 141/254 reads (56%) | catalogued as COSV99908254; called by muse, mutect2, varscan2
- CABP2 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs768734103, COSV53708793; called by muse, mutect2, varscan2
- CACNA1A | c.3827G>A p.R1276Q | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV64206552; called by muse, mutect2, varscan2
- CACNA1D | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 58/204 reads (28%) | catalogued as COSV55438145; called by muse, mutect2, varscan2
- CACNA1D | c.4839G>T p.Q1613H (on ENST00000350061 / NM_001128840.3; = p.Q1633H on NM_000720.4) | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99856507; called by muse, mutect2, varscan2
- CACNA1D | c.6205G>A p.E2069K (on ENST00000350061 / NM_001128840.3; = p.E2089K on NM_000720.4) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.562); catalogued as rs373783390; called by muse, mutect2, varscan2
- CACNA1E | c.6346C>T p.R2116C (on ENST00000367573 / NM_001205293.3; = p.R2073C on NM_000721.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs765523959, COSV62382695; called by muse, mutect2, varscan2
- CACNA1H | c.5023C>T p.R1675W | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760740366, COSV61993947; called by muse, varscan2
- CALCOCO1 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as COSV100017111; called by muse, mutect2, varscan2
- CAMK2G | c.403A>G p.R135G | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99989404; called by muse, mutect2, varscan2
- CAMKK2 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1451826262, COSV100242579; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 48/148 reads (32%) | catalogued as rs1375954479; called by mutect2, varscan2
- CAMTA1 | c.2779G>T p.A927S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57922011; called by muse, mutect2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 119/355 reads (34%) | catalogued as rs770159446; called by mutect2, varscan2
- CASP8 | c.626C>T p.S209L (on ENST00000432109 / NM_033355.3; = p.S226L on NM_001228.4) | Missense Mutation (SNP) | VAF 168/507 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1351320412, COSV51849767; called by muse, mutect2, varscan2
- CASP8 | c.701del p.G234Dfs*4 (on ENST00000432109 / NM_033355.3; = p.G251Dfs*4 on NM_001228.4) | Frame Shift Del (DEL) | VAF 89/340 reads (26%) | catalogued as COSV51844924; called by mutect2, pindel, varscan2
- CASP8AP2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs745563258, COSV99386732; called by muse, mutect2, varscan2
- CATSPER3 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99253885; called by muse, mutect2, varscan2
- CCDC17 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs774726919, COSV51971552; called by muse, mutect2, varscan2
- CCDC180 | c.4614del p.K1539Nfs*17 | Frame Shift Del (DEL) | VAF 84/244 reads (34%) | catalogued as rs1423532083; called by mutect2, pindel, varscan2
- CCDC57 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs370460701; called by muse, mutect2, varscan2
- CCDC80 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99244198; called by muse, mutect2, varscan2
- CCDC80 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52814717; called by muse, mutect2, varscan2
- CCIN | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as rs142836285, COSV58725324; called by muse, mutect2, varscan2
- CCNA2 | c.818del p.P273Qfs*3 | Frame Shift Del (DEL) | VAF 80/343 reads (23%) | catalogued as rs1560632032; called by mutect2, pindel, varscan2
- CCR5 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs764278401, CM104770, COSV52751490; called by muse, mutect2, varscan2
- CCT6A | c.748del p.Y250Tfs*11 | Frame Shift Del (DEL) | VAF 17/32 reads (53%) | catalogued as COSV51905804; called by mutect2, varscan2
- CD163 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 152/532 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as rs780185045, COSV63136816; called by muse, mutect2, varscan2
- CD22 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs776104112, COSV50061342, COSV50061536; called by muse, mutect2, varscan2
- CD300LB | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 100/399 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100075286; called by muse, varscan2
- CD34 | c.785del p.K262Sfs*6 | Frame Shift Del (DEL) | VAF 133/473 reads (28%) | catalogued as COSV60414017; called by mutect2, pindel, varscan2
- CD47 | c.942A>C p.K314N | Missense Mutation (SNP) | VAF 314/882 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100790091; called by mutect2, varscan2
- CD52 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 260/854 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs201908321; called by muse, mutect2
- CD7 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751672673, COSV100444756; called by muse, mutect2, varscan2
- CDADC1 | c.1373T>C p.M458T | Missense Mutation (SNP) | VAF 140/569 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV99212528; called by muse, mutect2, varscan2
- CDC42BPG | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs769398599, COSV61348063; called by muse, mutect2, varscan2
- CDC45 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.888); catalogued as rs551487753, COSV54247406; called by muse, mutect2, varscan2
- CDH16 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.152); catalogued as rs995411029, COSV100233629; called by muse, mutect2, varscan2
- CDH23 | c.2565A>C p.K855N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.152); catalogued as COSV99818663, COSV99824080; called by muse, mutect2, varscan2
- CDH4 | c.1232C>A p.A411E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100848403; called by muse, mutect2, varscan2
- CDK20 | c.955del p.H319Tfs*16 (on ENST00000325303 / NM_001039803.3; = p.H298Tfs*16 on NM_012119.4) | Frame Shift Del (DEL) | VAF 17/126 reads (13%) | catalogued as rs749463697; called by mutect2, pindel, varscan2
- CDK3 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770199924, COSV100043911; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4258C>T p.R1420W | Missense Mutation (SNP) | VAF 169/937 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs143596126, COSV100575047; called by muse, mutect2, varscan2
- CDON | c.3589G>A p.V1197I | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs911339564, COSV99700453; called by muse, mutect2, varscan2
- CDPF1 | c.41A>G p.E14G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as COSV99415097; called by muse, mutect2, varscan2
- CELA3A | c.501C>T p.T167= | Splice Region (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99266371; called by muse, mutect2, varscan2
- CELSR2 | c.3772T>G p.S1258A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs760258795, COSV99602990; called by muse, mutect2, varscan2
- CEMIP | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs199948256, COSV99585974; called by muse, mutect2, varscan2
- CEMIP | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.324); catalogued as COSV99585977; called by muse, mutect2, varscan2
- CENPJ | c.3887A>C p.K1296T | Missense Mutation (SNP) | VAF 238/657 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99692058; called by muse, mutect2, varscan2
- CENPV | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as COSV55333047; called by muse, mutect2, varscan2
- CEP112 | c.2810T>C p.L937P (on ENST00000392769 / NM_001353127.1; = p.L193P on NM_001037325.3) | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100438860; called by muse, mutect2, varscan2
- CEP170B | c.263G>A p.R88H (on ENST00000453495; = p.R18H on NM_015005.3) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1247117233, COSV101371384; called by muse, mutect2, varscan2
- CEP70 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99388791; called by muse, mutect2, varscan2
- CES1 | c.561del p.N188Tfs*28 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as COSV62086598; called by mutect2, pindel
- CFAP251 | c.320T>C p.M107T | Missense Mutation (SNP) | VAF 120/463 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99945549; called by muse, varscan2
- CFAP251 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 228/437 reads (52%) | catalogued as COSV99945551; called by muse, varscan2
- CFAP43 | c.3934C>T p.R1312C | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs201811267; called by muse, mutect2, varscan2
- CFAP46 | c.7622C>T p.A2541V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); catalogued as rs143790683, COSV54155598; called by muse, mutect2, varscan2
- CFAP65 | c.1319A>G p.Y440C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99838223; called by muse, mutect2, varscan2
- CHAT | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs376230019; called by muse, mutect2, varscan2
- CHD2 | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 39/730 reads (5%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.885); catalogued as COSV59120523; called by muse, mutect2
- CHD2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1041959719, COSV100560491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD2 | c.4044G>T p.K1348N | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV101244665; called by muse, mutect2
- CHD5 | c.3236G>A p.R1079Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV99312364; called by muse, mutect2, varscan2
- CHD5 | c.2282T>C p.I761T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99312368; called by muse, mutect2, varscan2
- CHMP2B | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99773205; called by muse, mutect2, varscan2
- CHODL | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100166578; called by muse, mutect2, varscan2
- CHRDL2 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as COSV99733517; called by muse, mutect2, varscan2
- CHRM2 | c.1334C>G p.A445G | Missense Mutation (SNP) | VAF 169/495 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV100280671, COSV100281046; called by muse, mutect2, varscan2
- CIITA | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs761597254, COSV60860278; called by muse, mutect2, varscan2
- CILK1 | c.1313G>A p.S438N (on ENST00000350082 / NM_001375397.1; = p.S431N on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 125/346 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV100607471; called by muse, mutect2, varscan2
- CILP | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143279369; called by muse, mutect2, varscan2
- CIZ1 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99476609; called by muse, mutect2, varscan2
- CKAP4 | c.1251G>T p.E417D | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100952387; called by muse, mutect2, varscan2
- CLDN9 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); catalogued as rs746271447, COSV100172032; called by muse, mutect2, varscan2
- CLDND1 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 165/483 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs748541120, COSV100360648; called by muse, mutect2, varscan2
- CLEC16A | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs763777406, COSV101277797; called by muse, mutect2, varscan2
- CNGB1 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99201386; called by muse, mutect2, varscan2
- CNKSR1 | c.1679G>A p.R560H (on ENST00000374253 / NM_001297647.2; = p.R553H on NM_006314.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs148602031; called by muse, mutect2, varscan2
- CNOT3 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1420624033, COSV99651459; called by muse, mutect2, varscan2
- CNTNAP4 | c.1070T>C p.M357T | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1350170549, COSV56693317; called by muse, mutect2, varscan2
- CNTNAP4 | c.2147C>T p.S716L | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571000371, COSV56664435; called by muse, mutect2, varscan2
- COBL | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372443929; called by muse, mutect2, varscan2
- COL11A1 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV62190911; called by muse, mutect2, varscan2
- COL16A1 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV99593489; called by muse, mutect2, varscan2
- COL3A1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1178112512, COSV58582183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV100649759; called by muse, mutect2, varscan2
- COMMD5 | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100295627; called by muse, mutect2, varscan2
- COQ8B | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99699264; called by muse, mutect2, varscan2
- CORO1A | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs1028173314, COSV99531796; called by muse, varscan2
- CPNE1 | c.1501G>A p.V501M (on ENST00000352393; = p.V506M on NM_003915.5) | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs143661266; called by muse, mutect2, varscan2
- CPSF6 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.905); catalogued as COSV99878967; called by muse, mutect2, varscan2
- CPT1A | c.779T>G p.L260R | Missense Mutation (SNP) | VAF 104/304 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99680539; called by muse, mutect2, varscan2
- CPXM1 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV101013672; called by muse, mutect2, varscan2
- CRACD | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1365781651, COSV51714358, COSV99948491; called by muse, mutect2, varscan2
- CREB3L3 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs751875949, COSV50176737; called by muse, mutect2, varscan2
- CREBBP | c.6451C>T p.R2151W | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as rs1361732490, COSV52115948; called by muse, mutect2, varscan2
- CRNKL1 | c.2150A>G p.Q717R | Missense Mutation (SNP) | VAF 102/331 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100131454; called by muse, mutect2, varscan2
- CRYGC | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs1469741282, COSV56408965; called by muse, mutect2, varscan2
- CSDE1 | c.1669G>A p.E557K (on ENST00000358528 / NM_001007553.3; = p.E526K on NM_007158.6) | Missense Mutation (SNP) | VAF 290/901 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV54757893, COSV99793981; called by muse, mutect2, varscan2
- CSKMT | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as rs778729080, COSV100648995; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 112/415 reads (27%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.1583G>A p.R528Q (on ENST00000297405 / NM_001363185.1; = p.R424Q on NM_052900.3) | Missense Mutation (SNP) | VAF 184/571 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs779272178, COSV52147660, COSV52147973; called by muse, mutect2, varscan2
- CSNK1A1 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.182); catalogued as rs865943998, COSV55793928; called by muse, mutect2, varscan2
- CSNK1G3 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 103/255 reads (40%) | catalogued as COSV100631316; called by muse, mutect2, varscan2
- CTDSPL2 | c.155T>A p.I52N | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99526499; called by muse, mutect2, varscan2
- CTSB | c.536G>A p.C179Y | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100565795; called by muse, mutect2, varscan2
- CTSV | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 141/429 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as rs764260070, COSV99414293; called by muse, varscan2
- CTSV | c.906C>A p.S302R | Missense Mutation (SNP) | VAF 72/267 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52345941; called by muse, varscan2
- CTTNBP2 | c.2573G>A p.S858N | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV50457791, COSV99352928; called by muse, mutect2, varscan2
- CUBN | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV64714418; called by muse, mutect2, varscan2
- CUX2 | c.3581C>T p.S1194L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55648204; called by muse, mutect2
- CYP26A1 | c.1353_1355del p.L452del | In Frame Del (DEL) | VAF 22/70 reads (31%) | catalogued as rs1362434045; called by pindel, varscan2
- CYP2A7 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 77/127 reads (61%) | catalogued as COSV99393639; called by muse, mutect2, varscan2
- DACT1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 101/291 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as COSV100241564; called by muse, mutect2, varscan2
- DAGLA | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs536638905, COSV57198472; called by muse, mutect2, varscan2
- DBH | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747491059, COSV55040891; called by muse, varscan2
- DCAF4L2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1459776004, COSV60476643; called by muse, mutect2, varscan2
- DCHS1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as rs763608227, COSV100201425; called by muse, mutect2, varscan2
- DDI2 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100197392; called by muse, mutect2, varscan2
- DDX27 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs761573110, COSV100874636; called by muse, mutect2, varscan2
- DENND4B | c.3934C>T p.R1312C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs754408493, COSV100768371; called by muse, mutect2, varscan2
- DENND5A | c.3388C>T p.R1130* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as rs1381160481, COSV60231569; called by muse, mutect2, varscan2
- DGAT2L6 | c.746T>C p.F249S | Missense Mutation (SNP) | VAF 103/371 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV100283875; called by muse, mutect2, varscan2
- DGCR8 | c.1642A>G p.I548V | Missense Mutation (SNP) | VAF 113/305 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV100707791; called by muse, mutect2, varscan2
- DGKD | c.2689G>A p.A897T (on ENST00000264057 / NM_152879.3; = p.A853T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as rs765978079, COSV51080025; called by muse, mutect2, varscan2
- DGKG | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 100/275 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs373512874; called by muse, mutect2, varscan2
- DHRS2 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs562008596, COSV99158709; called by muse, mutect2, varscan2
- DHX30 | c.3403G>A p.V1135M (on ENST00000445061 / NM_138615.3; = p.V1096M on NM_014966.3) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs753692624, COSV99274638; called by muse, mutect2, varscan2
- DIAPH2 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 268/450 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs201017046, COSV100230570; called by muse, mutect2, varscan2
- DLG2 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 208/705 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV99712430; called by muse, mutect2, varscan2
- DLG3 | c.1280G>A p.R427H (on ENST00000374360 / NM_021120.4; = p.R90H on NM_020730.3) | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs775293712, COSV52079852; called by muse, mutect2, varscan2
- DLK2 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs768837940, COSV99766569; called by muse, mutect2, varscan2
- DNAH10 | c.11775C>A p.S3925R (on ENST00000409039; = p.S3864R on NM_207437.3) | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as COSV101291920; called by muse, mutect2, varscan2
- DNAH12 | c.252+1G>C p.X84_splice | Splice Site (SNP) | VAF 204/628 reads (32%) | catalogued as COSV100244313; called by muse, mutect2, varscan2
- DNAH17 | c.2986G>C p.D996H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV67758939; called by muse, mutect2, varscan2
- DNAH2 | c.6296C>T p.A2099V | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as rs1432599803, COSV101208976; called by muse, mutect2, varscan2
- DNAJC1 | c.975dup p.Q326Tfs*4 | Frame Shift Ins (INS) | VAF 328/1138 reads (29%) | catalogued as rs1233931895; called by mutect2, pindel, varscan2
- DNM1L | c.1771G>T p.G591* (on ENST00000549701 / NM_012062.5; = p.G554* on NM_005690.4) | Nonsense Mutation (SNP) | VAF 224/966 reads (23%) | catalogued as COSV99845740; called by muse, mutect2, varscan2
- DOCK10 | c.280T>C p.S94P | Missense Mutation (SNP) | VAF 111/346 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV99287472; called by muse, mutect2, varscan2
- DOCK11 | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 74/1154 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99352791; called by muse, mutect2
- DOCK2 | c.3767A>C p.E1256A | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV99910125; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK7 | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV100403119; called by muse, mutect2, varscan2
- DOP1A | c.2750A>G p.Q917R | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99380858; called by muse, varscan2
- DOP1B | c.2541dup p.G848Wfs*77 | Frame Shift Ins (INS) | VAF 22/142 reads (15%) | catalogued as rs750520568; called by mutect2, varscan2
- DOP1B | c.5636C>A p.A1879D | Missense Mutation (SNP) | VAF 174/399 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.102); catalogued as COSV101215011; called by muse, mutect2, varscan2
- DRAXIN | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); catalogued as rs775629878, COSV99610542; called by muse, mutect2, varscan2
- DST | c.6046G>A p.D2016N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV99750670; called by muse, mutect2, varscan2
- DTNBP1 | c.779_781del p.G260del | In Frame Del (DEL) | VAF 61/195 reads (31%) | catalogued as rs760628074; called by pindel, varscan2
- DUSP6 | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV99683932; called by muse, mutect2, varscan2
- DVL2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865809670, COSV99138305; called by muse, mutect2, varscan2
- DYNC2H1 | c.5744G>T p.C1915F | Missense Mutation (SNP) | VAF 19/698 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV100517437; called by muse, mutect2
- DYRK1A | c.2138G>A p.G713D | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV58709305; called by muse, mutect2, varscan2
- DYRK3 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV65605481; called by muse, mutect2, varscan2
- DZANK1 | c.41T>C p.L14S | Missense Mutation (SNP) | VAF 191/485 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52755017; called by muse, mutect2, varscan2
- ECHDC2 | c.677C>T p.A226V (on ENST00000371522 / NM_001198961.2; = p.A195V on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV100597431; called by muse, mutect2, varscan2
- ECM2 | c.30dup p.L11Sfs*8 | Frame Shift Ins (INS) | VAF 33/173 reads (19%) | catalogued as rs752987091; called by mutect2, varscan2
- ECPAS | c.1783A>G p.M595V | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV99397441; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2168C>T p.T723M | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1231165786, COSV62569708; called by muse, mutect2, varscan2
- EFCAB7 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as rs1383841396, COSV52133747; called by muse, mutect2, varscan2
- EIF3A | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770069171, COSV64961783; called by muse, mutect2, varscan2
- EIF4G3 | c.2948A>G p.N983S | Missense Mutation (SNP) | VAF 206/534 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as rs767874521, COSV99943117; called by muse, mutect2, varscan2
- EIF5B | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 202/585 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1254050576, COSV99176783; called by muse, mutect2, varscan2
- ELF5 | c.343G>A p.G115S (on ENST00000312319 / NM_198381.2; = p.G105S on NM_001422.4) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778628535, COSV99141146; called by muse, mutect2, varscan2
- ELL | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.098); catalogued as rs574270231, COSV53211509; called by muse, mutect2, varscan2
- ELOVL5 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 95/384 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs766390073, COSV58651232; called by muse, mutect2, varscan2
- ELP2 | c.332A>G p.Y111C | Missense Mutation (SNP) | VAF 190/636 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100626718; called by muse, mutect2, varscan2
- ENTPD4 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs556405061, COSV62268617; called by muse, mutect2, varscan2
- ENTPD6 | c.372del p.R125Efs*6 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs769657862; called by mutect2, pindel, varscan2
- EPB41L1 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 180/578 reads (31%) | catalogued as COSV99148861; called by muse, mutect2, varscan2
- EPB41L4B | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 180/1183 reads (15%) | catalogued as rs377479255; called by muse, mutect2, varscan2
- EPHA3 | c.1938del p.E647Rfs*9 | Frame Shift Del (DEL) | VAF 78/314 reads (25%) | catalogued as rs1467832547; called by mutect2, pindel, varscan2
- EPHB6 | c.426C>A p.D142E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101235936; called by muse, varscan2
- EPHB6 | c.1508A>G p.N503S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100844109; called by muse, mutect2, varscan2
- EPS8 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 142/554 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1431122681, COSV99842604; called by muse, mutect2, varscan2
- EPYC | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 106/453 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1183549045, COSV53802508; called by muse, mutect2, varscan2
- ERBB3 | c.2693G>A p.G898D | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99915667; called by muse, mutect2, varscan2
- ERCC6 | c.2338G>A p.V780I | Missense Mutation (SNP) | VAF 221/649 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762128995, COSV63389649; called by muse, mutect2, varscan2
- ESR1 | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.533); catalogued as rs141662120, COSV52794676; called by muse, mutect2, varscan2
- ESYT3 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs372599591; called by muse, mutect2, varscan2
- EXO1 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 87/336 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs751493652, COSV100799600; called by muse, mutect2, varscan2
- F11R | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99230734; called by muse, mutect2, varscan2
- F12 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99499400; called by muse, mutect2, varscan2
- F5 | c.1976-2A>G p.X659_splice | Splice Site (SNP) | VAF 43/133 reads (32%) | catalogued as COSV63122920, COSV63124448; called by muse, mutect2, varscan2
- FADS2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53901218, COSV99609175; called by muse, mutect2, varscan2
- FAIM2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as rs145638550; called by muse, mutect2, varscan2
- FAM118B | c.174A>T p.Q58H | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV100796810; called by muse, mutect2, varscan2
- FAM151B | c.756del p.K252Nfs*48 | Frame Shift Del (DEL) | VAF 68/278 reads (24%) | catalogued as rs764889708; called by mutect2, varscan2
- FAM160B1 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.531); catalogued as rs754122876, COSV65088772; called by muse, mutect2, varscan2
- FAM171A1 | c.2410A>G p.T804A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100967992; called by muse, mutect2, varscan2
- FAM171A1 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.685); catalogued as rs776191844, COSV65314038, COSV65318372; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 86/239 reads (36%) | catalogued as rs768952789; called by mutect2, varscan2
- FAM222B | c.719dup p.N241Efs*27 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs764940150; called by mutect2, varscan2
- FARP2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 165/530 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1176974527, COSV99883813; called by muse, mutect2, varscan2
- FAT3 | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV53151029; called by muse, mutect2, varscan2
- FAT3 | c.12490G>A p.V4164I | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.024); catalogued as rs765324804, COSV53151072; called by muse, mutect2, varscan2
- FAT4 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101271814, COSV67887318; called by muse, mutect2, varscan2
- FAT4 | c.14564T>C p.M4855T | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100627182; called by muse, mutect2, varscan2
- FBXL20 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 149/516 reads (29%) | catalogued as COSV99233699; called by muse, mutect2, varscan2
- FBXL4 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 278/732 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1187735129, COSV100013833; called by muse, mutect2, varscan2
- FBXO15 | c.925C>A p.L309M | Missense Mutation (SNP) | VAF 175/788 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV99503008; called by muse, mutect2, varscan2
- FBXO9 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as rs760965873, COSV99762225; called by muse, mutect2, varscan2
- FBXW4 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1418569736, COSV100489341; called by muse, mutect2, varscan2
- FCHO2 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 123/327 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs368140227; called by muse, mutect2, varscan2
- FCN1 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 60/410 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs372242075; called by muse, varscan2
- FCRL5 | c.1518G>C p.Q506H | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100708494; called by muse, mutect2, varscan2
- FCRLB | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV100396070; called by muse, mutect2, varscan2
- FEN1 | c.733C>G p.R245G | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV99952766; called by muse, mutect2, varscan2
- FGD6 | c.989G>A p.C330Y | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs746127225, COSV100676342; called by muse, mutect2, varscan2
- FIGNL1 | c.926del p.K309Sfs*16 | Frame Shift Del (DEL) | VAF 68/218 reads (31%) | catalogued as rs1216734611; called by mutect2, varscan2
- FKBP10 | c.299C>A p.T100N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.871); catalogued as COSV100387715; called by muse, varscan2
- FKBP15 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 205/541 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs760349713, COSV53037806; called by muse, mutect2, varscan2
- FKBPL | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1167063174, COSV100913532; called by muse, mutect2, varscan2
- FLG | c.9907G>A p.G3303R | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778135195, COSV64235820; called by muse, mutect2, varscan2
- FLG | c.4868G>A p.R1623Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs201196640, COSV64247556; called by muse, mutect2, varscan2
- FLG | c.3989G>A p.G1330D | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs752028692, COSV64236240; called by muse, mutect2, varscan2
- FLNB | c.7559C>T p.A2520V | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.853); catalogued as COSV99911628; called by muse, mutect2, varscan2
- FN1 | c.7027G>T p.E2343* (on ENST00000359671 / NM_001365524.2; = p.E2312* on NM_002026.4) | Nonsense Mutation (SNP) | VAF 91/288 reads (32%) | catalogued as COSV100115804, COSV60549918; called by muse, mutect2, varscan2
- FOXD4 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1231318195, COSV58702806; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FOXP1 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs1348187295, COSV59519444; called by muse, varscan2
- FREM1 | c.4891A>G p.T1631A | Missense Mutation (SNP) | VAF 72/570 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV101083716; called by muse, mutect2, varscan2
- FRG2C | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.644); catalogued as rs1179297288; called by muse, mutect2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMPD1 | c.3795G>T p.E1265D | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.037); catalogued as rs201302424, COSV66701147; called by muse, mutect2, varscan2
- FRMPD2 | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1226210347, COSV100563469; called by muse, mutect2, varscan2
- FRY | c.4867del p.L1623Wfs*22 | Frame Shift Del (DEL) | VAF 31/107 reads (29%) | catalogued as COSV100968937, COSV66566354, COSV66574218; called by mutect2, pindel, varscan2
- FTHL17 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); catalogued as COSV63266742; called by muse, mutect2, varscan2
- FXN | c.221C>T p.T74M (on ENST00000377270; = p.T149M on NM_000144.5) | Missense Mutation (SNP) | VAF 138/667 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551991546, COSV101040031; called by muse, mutect2, varscan2
- FZD3 | c.1031T>C p.I344T | Missense Mutation (SNP) | VAF 276/717 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV99527827; called by muse, mutect2, varscan2
- GABRG2 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.04); catalogued as COSV100729499; called by muse, varscan2
- GABRG3 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61521069; called by muse, mutect2, varscan2
- GALNT10 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99768134; called by muse, mutect2, varscan2
- GALNT14 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100204031; called by muse, mutect2, varscan2
- GALNT17 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781199608, COSV61153886, COSV61176768; called by muse, mutect2, varscan2
- GCFC2 | c.1739G>A p.S580N | Missense Mutation (SNP) | VAF 243/746 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.037); catalogued as rs1558736689, COSV100319336; called by muse, mutect2, varscan2
- GDF6 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs1467807484, COSV54623834; called by mutect2, varscan2
- GET4 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs759801442, COSV56256593; called by muse, mutect2
- GJB1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs749796053, COSV62139879; called by muse, mutect2, varscan2
- GJB3 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 108/277 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs976148533, COSV64904436; called by muse, mutect2, varscan2
- GLI2 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100082244; called by muse, mutect2, varscan2
- GLI3 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 128/377 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749940791, COSV101229712; called by muse, mutect2, varscan2
- GLRA3 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); catalogued as COSV99926893; called by muse, mutect2, varscan2
- GMPS | c.613A>C p.N205H | Missense Mutation (SNP) | VAF 44/534 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99902858; called by muse, mutect2
- GNL2 | c.1868G>T p.R623I | Missense Mutation (SNP) | VAF 96/283 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99953458; called by muse, mutect2, varscan2
- GNPDA2 | c.282del p.F94Lfs*6 | Frame Shift Del (DEL) | VAF 90/267 reads (34%) | catalogued as rs1489322870; called by mutect2, pindel, varscan2
- GPBP1 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 93/241 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV53310371; called by muse, mutect2, varscan2
- GPD1 | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99993710; called by muse, mutect2, varscan2
- GPD1 | c.364del p.X122_splice | Splice Site (DEL) | VAF 26/71 reads (37%) | catalogued as rs1224277565, CS120252; called by mutect2, pindel, varscan2
- GPHB5 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.076); catalogued as COSV100030140; called by muse, mutect2, varscan2
- GPI | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs748408705, COSV62893793; called by muse, mutect2, varscan2
- GPR101 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV53238534, COSV99981240; called by muse, mutect2, varscan2
- GPR12 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101197935; called by muse, mutect2, varscan2
- GPR149 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs1200638787, COSV101078089; called by muse, mutect2, varscan2
- GPR173 | c.1012A>G p.I338V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.1); catalogued as rs782095276, COSV100212010; called by muse, mutect2, varscan2
- GPR50 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 385/659 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as rs768655839, COSV54442018; called by muse, mutect2, varscan2
- GPSM2 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 134/416 reads (32%) | catalogued as rs776770855, COSV51441866; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 80/268 reads (30%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK4 | c.1729C>T p.H577Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV101483419; called by muse, mutect2, varscan2
- GRIN2B | c.3562G>A p.G1188S | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as rs367543149, COSV101662898; ClinVar: not provided; called by muse, mutect2, varscan2
- GRIP2 | c.1585C>T p.H529Y (on ENST00000619221; = p.H432Y on NM_001080423.4) | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.897); catalogued as COSV99816899; called by muse, mutect2, varscan2
- GRM1 | c.1240A>G p.I414V | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV99263804; called by muse, mutect2, varscan2
- GRM6 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs760164627, COSV51436761; called by muse, mutect2, varscan2
- GSDME | c.314del p.G105Afs*5 | Frame Shift Del (DEL) | VAF 63/236 reads (27%) | catalogued as rs755613828; called by mutect2, pindel, varscan2
- GSS | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as rs780544238, COSV53811444; called by muse, mutect2, varscan2
- GTF3C2 | c.2665T>C p.F889L | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1345499152, COSV99272115; called by muse, mutect2, varscan2
- H3C13 | c.381G>T p.L127F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100516024; called by muse, mutect2, varscan2
- HAL | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765722855, COSV54117815; called by muse, mutect2, varscan2
- HBS1L | c.585del p.G196Dfs*40 | Frame Shift Del (DEL) | VAF 31/174 reads (18%) | catalogued as rs1412060705; called by mutect2, pindel, varscan2
- HCN1 | c.2003A>G p.Y668C | Missense Mutation (SNP) | VAF 117/385 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.887); catalogued as COSV100298366; called by muse, mutect2, varscan2
- HCN1 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57520200, COSV57522009; called by muse, mutect2, varscan2
- HDAC4 | c.2989-1G>T p.X997_splice | Splice Site (SNP) | VAF 30/102 reads (29%) | catalogued as COSV100612617; called by muse, mutect2, varscan2
- HDAC4 | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100612618; called by muse, mutect2, varscan2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs771658394; called by mutect2, pindel, varscan2
- HECW1 | c.3815G>A p.R1272Q | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs367661051, COSV67824610; called by muse, mutect2, varscan2
- HELZ | c.2716C>T p.R906* | Nonsense Mutation (SNP) | VAF 67/297 reads (23%) | catalogued as rs1312644072, COSV100698488; called by muse, mutect2, varscan2
- HERC2 | c.11100G>T p.W3700C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99870679; called by muse, mutect2, varscan2
- HIF3A | c.784G>A p.A262T (on ENST00000377670 / NM_152795.4; = p.A193T on NM_022462.4) | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.815); catalogued as COSV52199600; called by muse, mutect2, varscan2
- HJV | c.644C>T p.T215I (on ENST00000336751 / NM_213653.4; = p.T102I on NM_145277.5) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382186; called by muse, mutect2, varscan2
- HK3 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99457766; called by muse, mutect2, varscan2
- HLCS | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746588785, COSV100357815; called by muse, varscan2
- HLX | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV65045727; called by muse, mutect2
- HMGXB4 | c.1754A>G p.Q585R | Missense Mutation (SNP) | VAF 106/321 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV99329893; called by muse, mutect2, varscan2
- HNRNPC | c.829del p.D277Mfs*6 (on ENST00000420743; = p.D264Mfs*6 on NM_004500.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 233/788 reads (30%) | catalogued as rs1566590411, COSV100193248; called by mutect2, pindel, varscan2
- HNRNPF | c.528A>G p.I176M | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as COSV100562954; called by muse, mutect2, varscan2
- HNRNPL | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs1228792246, COSV55492313; called by muse, mutect2, varscan2
- HUNK | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1233392236, COSV54229194; called by muse, mutect2, varscan2
- HYDIN | c.7694G>T p.G2565V | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59270227, COSV99991871; called by muse, mutect2, varscan2
- HYDIN | c.6440G>A p.R2147H | Missense Mutation (SNP) | VAF 99/364 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs558300717, COSV99991659; called by muse, mutect2, varscan2
- IARS1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 106/588 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV100986772; called by muse, mutect2, varscan2
- IDE | c.1706del p.L569Cfs*45 | Frame Shift Del (DEL) | VAF 102/268 reads (38%) | catalogued as rs771790236; called by mutect2, varscan2
- IDH2 | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1472715809, COSV99184073; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs750779916, COSV60737300; called by mutect2, varscan2
- IFNLR1 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.059); catalogued as rs764742091, COSV100551961; called by muse, mutect2, varscan2
- IFT172 | c.3386C>T p.A1129V | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558367670, COSV99561710; called by muse, mutect2, varscan2
- IGF1R | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51317159; called by muse, mutect2, varscan2
- IGKV1-5 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs764059454; called by muse, mutect2, varscan2
- IGSF1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.992); catalogued as COSV63838663; called by muse, mutect2
- IL17RA | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV100082847; called by muse, mutect2, varscan2
- IL17RB | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749453165, COSV99213537; called by muse, mutect2, varscan2
- IL18RAP | c.87del p.K29Nfs*66 | Frame Shift Del (DEL) | VAF 70/257 reads (27%) | catalogued as rs756319084; called by mutect2, pindel, varscan2
- IL1RL1 | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 86/296 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs770476261, COSV99293554; called by muse, mutect2, varscan2
- IMPG1 | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 122/438 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as COSV100885933; called by muse, mutect2, varscan2
- INSRR | c.2757del p.L920Cfs*37 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs772259106; called by mutect2, pindel, varscan2
- INSRR | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV100947093; called by muse, mutect2, varscan2
- IP6K2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.963); catalogued as rs372776558, COSV99583671; called by muse, mutect2
- IPMK | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 57/186 reads (31%) | catalogued as COSV64243565; called by muse, mutect2, varscan2
- IPMK | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 166/488 reads (34%) | catalogued as rs758099009, COSV100880207; called by mutect2, varscan2
- IPO4 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs369678433; called by muse, mutect2, varscan2
- IPO9 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 110/312 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as rs757892876, COSV100843317; called by muse, mutect2, varscan2
- IRF9 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1290580672, COSV100138029; called by muse, mutect2, varscan2
- IRS4 | c.1614G>T p.Q538H | Missense Mutation (SNP) | VAF 54/85 reads (64%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV100929411; called by muse, mutect2, varscan2
- ISLR2 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100679371; called by muse, mutect2, varscan2
- ITPK1 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.17); catalogued as rs757596570, COSV50900004; called by muse, mutect2, varscan2
- ITPRIP | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs776290130, COSV99532381, COSV99532416; called by muse, mutect2, varscan2
- ITSN2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 261/760 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs777801668, COSV100742610; called by muse, mutect2, varscan2
- IZUMO1 | c.475T>C p.C159R | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99710453; called by muse, mutect2, varscan2
- JAK3 | c.2159G>A p.S720N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV101512874; called by muse, mutect2, varscan2
- JTB | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.038); catalogued as rs778131192, COSV99665590; called by muse, mutect2, varscan2
- JUP | c.938A>G p.Q313R | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.086); catalogued as COSV100159306; called by muse, mutect2, varscan2
- KALRN | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV99561987; called by muse, mutect2, varscan2
- KBTBD4 | c.1214C>G p.T405R | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100442811; called by muse, mutect2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCND1 | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99501688; called by muse, mutect2, varscan2
- KCND2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs756823168, COSV58586030; called by muse, mutect2
- KCNE4 | c.397del p.E133Rfs*3 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs760505003; called by mutect2, varscan2
- KCNG4 | c.1544C>A p.P515H | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as COSV100376893; called by muse, mutect2
- KCNJ3 | c.848T>G p.L283R | Missense Mutation (SNP) | VAF 107/318 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99715184, COSV99715296; called by muse, mutect2, varscan2
- KCNJ5 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.79); catalogued as COSV100610537; called by muse, mutect2, varscan2
- KCTD19 | c.2301dup p.V768Rfs*12 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs759860142; called by mutect2, varscan2
- KCTD3 | c.1910C>T p.T637I | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as rs1558248637, COSV99378767; called by muse, mutect2, varscan2
- KDM2A | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 120/318 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100445373; called by muse, mutect2, varscan2
- KDM4C | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 129/682 reads (19%) | catalogued as rs779861232, COSV67190140; called by muse, mutect2, varscan2
- KDR | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1139774, COSV55763897; called by muse, mutect2, varscan2
- KIAA0753 | c.1914del p.K638Nfs*18 | Frame Shift Del (DEL) | VAF 415/1414 reads (29%) | catalogued as COSV63817190; called by mutect2, pindel, varscan2
- KIAA1549 | c.5276del p.P1759Rfs*66 | Frame Shift Del (DEL) | VAF 120/382 reads (31%) | catalogued as COSV54318123; called by mutect2, pindel, varscan2
- KIAA1958 | c.1344G>T p.K448N | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100515814; called by muse, mutect2
- KIF24 | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 110/211 reads (52%) | catalogued as rs765069486, COSV100799096; called by muse, mutect2, varscan2
- KIF3C | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99267011; called by muse, mutect2, varscan2
- KIF5B | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 239/713 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs760268366, COSV100191333; called by muse, mutect2, varscan2
- KIFAP3 | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 113/287 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs766097860, COSV100846691; called by muse, mutect2, varscan2
- KIRREL3 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as rs374832017; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 25/56 reads (45%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 22/125 reads (18%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KMT2D | c.9305del p.P3102Lfs*17 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as COSV99040252, COSV99983483; called by pindel, varscan2
- KPNA4 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100514962; called by muse, mutect2, varscan2
- KRT31 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs748743219, COSV52435034; called by muse, mutect2
- KSR1 | c.652G>T p.A218S (on ENST00000644974 / NM_001367810.1; = p.A81S on NM_014238.2) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV99257912; called by muse, mutect2, varscan2
- LACTB2 | c.309dup p.L104Tfs*28 | Frame Shift Ins (INS) | VAF 225/804 reads (28%) | catalogued as rs773915769; called by mutect2, pindel, varscan2
- LAG3 | c.512-1G>A p.X171_splice | Splice Site (SNP) | VAF 19/33 reads (58%) | catalogued as COSV99179875; called by muse, mutect2, varscan2
- LAMA1 | c.6842C>A p.S2281Y | Missense Mutation (SNP) | VAF 91/402 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV101054880; called by muse, mutect2, varscan2
- LAMA1 | c.2263G>A p.G755S | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1266955784, COSV67543328; called by muse, mutect2, varscan2
- LAMA3 | c.7594G>A p.D2532N (on ENST00000313654 / NM_198129.4; = p.D923N on NM_000227.6) | Missense Mutation (SNP) | VAF 59/310 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99333881; called by muse, mutect2, varscan2
- LAMB3 | c.3157C>T p.Q1053* | Nonsense Mutation (SNP) | VAF 32/81 reads (40%) | catalogued as COSV99151629; called by muse, mutect2, varscan2
- LARGE1 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 90/259 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.166); catalogued as rs138938225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LETM1 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); catalogued as rs1433033198, COSV100245174; called by muse, mutect2, varscan2
- LGI2 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101180740, COSV66122851; called by muse, mutect2, varscan2
- LIG1 | c.1502T>C p.M501T | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99618453; called by muse, mutect2, varscan2
- LIMS2 | c.718_720del p.K240del (on ENST00000355119 / NM_001161403.3; = p.K264del on NM_017980.4) | In Frame Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs1348506135; called by pindel, varscan2
- LINGO4 | c.1397A>G p.D466G | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.131); catalogued as COSV100764922; called by muse, varscan2
- LRCH4 | c.223C>T p.L75= | Splice Region (SNP) | VAF 3/19 reads (16%) | catalogued as COSV53828352; called by muse, mutect2
- LRFN2 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs771240052, COSV57832901; called by muse, mutect2, varscan2
- LRP1 | c.11968G>A p.E3990K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.13); catalogued as rs773851515, COSV99674286; called by muse, mutect2, varscan2
- LRRC17 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs752823104, COSV50866456, COSV99978183; called by muse, mutect2, varscan2
- LRRC31 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.901); catalogued as COSV99246289, COSV99246560; called by muse, mutect2, varscan2
- LRRC42 | c.236_237del p.E79Gfs*26 | Frame Shift Del (DEL) | VAF 30/113 reads (27%) | catalogued as rs1210520853; called by pindel, varscan2
- LRRC74A | c.1232A>C p.N411T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV99372158; called by muse, mutect2, varscan2
- LRRC8A | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.48); catalogued as COSV99396222; called by muse, mutect2, varscan2
- LRRK1 | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99437175, COSV99437437; called by muse, mutect2, varscan2
- LRRK2 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.181); catalogued as rs281865040, CM074927, COSV54164473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRK2 | c.6332_6335del p.I2111Nfs*4 | Frame Shift Del (DEL) | VAF 96/446 reads (22%) | catalogued as rs747108466; called by pindel, varscan2
- LRRTM1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99701699; called by muse, mutect2, varscan2
- LSM3 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 50/140 reads (36%) | catalogued as rs748145947, COSV53203904; called by muse, mutect2, varscan2
- LSM5 | c.142+1G>A p.X48_splice | Splice Site (SNP) | VAF 93/282 reads (33%) | catalogued as COSV56167640; called by muse, mutect2, varscan2
- LSMEM1 | c.38T>A p.I13N | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100456203; called by muse, mutect2, varscan2
- LTF | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs200379115, COSV99206757; called by muse, mutect2, varscan2
- LUM | c.511C>A p.L171M | Missense Mutation (SNP) | VAF 122/464 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99898874; called by muse, mutect2, varscan2
- LUZP1 | c.2810dup p.T938Nfs*5 | Frame Shift Ins (INS) | VAF 64/299 reads (21%) | catalogued as COSV56503887; called by pindel, varscan2
- LVRN | c.1516-1G>T p.X506_splice | Splice Site (SNP) | VAF 178/514 reads (35%) | catalogued as COSV100773313, COSV63497106; called by muse, mutect2, varscan2
- MACC1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs535198484, COSV100255314; called by muse, mutect2, varscan2
- MACIR | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1554237627, COSV60635576; called by muse, mutect2, varscan2
- MAGEC2 | c.1087A>G p.S363G | Missense Mutation (SNP) | VAF 164/231 reads (71%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as COSV99909375; called by muse, mutect2, varscan2
- MAP4K1 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1484809303, COSV67710737; called by muse, mutect2, varscan2
- MAPKAP1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 62/361 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.354); catalogued as rs1008519449, COSV99784316; called by muse, mutect2, varscan2
- MAST3 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs748960066, COSV53227635, COSV99444309; called by muse, mutect2
- MAST3 | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1178040525, COSV99444313; called by muse, mutect2
- MATK | c.265G>A p.V89I (on ENST00000310132 / NM_139355.3; = p.V90I on NM_002378.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs774774723, COSV100035808, COSV59556653; called by muse, mutect2, varscan2
- MCCC1 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs200031275, COSV99659328; called by muse, mutect2, varscan2
- MCOLN3 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 134/383 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.634); catalogued as rs1188765626, COSV100352557; called by muse, mutect2, varscan2
- MDN1 | c.7057A>G p.S2353G | Missense Mutation (SNP) | VAF 23/339 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101020731; called by muse, mutect2
- MDN1 | c.2015C>A p.P672H | Missense Mutation (SNP) | VAF 111/286 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101020732; called by muse, mutect2, varscan2
- MDN1 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 215/696 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs775308932, COSV65517211; called by muse, mutect2, varscan2
- MEGF8 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as rs926015247, COSV52075537; called by muse, mutect2, varscan2
- MEGF8 | c.7247G>A p.R2416H (on ENST00000251268 / NM_001271938.2; = p.R2349H on NM_001410.3) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs756370726, COSV52095274; called by muse, mutect2, varscan2
- MEIS2 | c.793G>T p.G265C (on ENST00000561208 / NM_170675.5; = p.G252C on NM_002399.3) | Missense Mutation (SNP) | VAF 257/481 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99575702; called by muse, varscan2
- MFSD5 | c.1222A>G p.M408V | Missense Mutation (SNP) | VAF 152/293 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs371060411; called by muse, mutect2, varscan2
- MGA | c.7303C>T p.R2435W (on ENST00000219905 / NM_001164273.1; = p.R2226W on NM_001080541.2) | Missense Mutation (SNP) | VAF 118/229 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779811318, COSV54947919; called by muse, mutect2, varscan2
- MGAT5B | c.1001del p.T334Kfs*4 | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | catalogued as COSV56933715; called by mutect2, pindel, varscan2
- MGRN1 | c.142del p.H48Tfs*13 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | catalogued as COSV52148537; called by pindel, varscan2
- MGST1 | c.405del p.F135Lfs*15 | Frame Shift Del (DEL) | VAF 312/1240 reads (25%) | catalogued as rs778971425; called by mutect2, varscan2
- MICALL1 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs897655503, COSV99316989; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 30/46 reads (65%) | catalogued as rs762448666; called by mutect2, varscan2
- MIER3 | c.302T>C p.M101T | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV100423506; called by muse, mutect2, varscan2
- MINDY4 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 128/378 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs905893541, COSV99518111; called by muse, mutect2, varscan2
- MIPEP | c.1357C>A p.R453S | Missense Mutation (SNP) | VAF 71/252 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV101193004; called by muse, mutect2, varscan2
- MLF1 | c.746C>G p.S249* | Nonsense Mutation (SNP) | VAF 34/347 reads (10%) | catalogued as COSV100575939; called by muse, mutect2, varscan2
- MMP15 | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.601); catalogued as COSV99539236; called by muse, mutect2, varscan2
- MMP25 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs200558581; called by mutect2, varscan2
- MORC1 | c.1331-2del p.X444_splice | Splice Site (DEL) | VAF 18/128 reads (14%) | catalogued as rs758380552, COSV99227961; called by pindel, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 40/105 reads (38%) | catalogued as rs777649506, COSV53202254; called by mutect2, varscan2
- MPI | c.23C>A p.P8Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV100086206; called by muse, mutect2, varscan2
- MR1 | c.689del p.P230Qfs*5 | Frame Shift Del (DEL) | VAF 24/137 reads (18%) | catalogued as rs1254492579; called by mutect2, pindel, varscan2
- MRGPRD | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100482921; called by muse, mutect2, varscan2
- MROH2B | c.1367C>A p.T456N | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.964); catalogued as rs746281100, COSV68186680; called by muse, mutect2, varscan2
- MRPL50 | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 70/410 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100879785; called by muse, mutect2, varscan2
- MRPS9 | c.511A>G p.N171D | Missense Mutation (SNP) | VAF 159/521 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99305852; called by muse, mutect2, varscan2
- MSL1 | c.800G>A p.R267Q (on ENST00000398532 / NM_001365919.1; = p.R4Q on NM_001012241.2) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1367096563, COSV100278004; called by muse, mutect2, varscan2
- MSX2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1201449653, COSV53327472; called by muse, mutect2, varscan2
- MTG1 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV100448664; called by muse, mutect2, varscan2
- MVK | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 92/155 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV99949853; called by muse, mutect2, varscan2
- MYCBP2 | c.6940G>T p.A2314S (on ENST00000357337; = p.A2352S on NM_015057.5) | Missense Mutation (SNP) | VAF 240/658 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV62031727; called by muse, mutect2, varscan2
- MYCBPAP | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.15); catalogued as COSV100087612; called by muse, mutect2, varscan2
- MYH3 | c.208del p.L70Wfs*11 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | catalogued as COSV56863477; called by mutect2, pindel, varscan2
- MYO10 | c.4870G>A p.G1624S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.674); catalogued as COSV57016812; called by muse, mutect2, varscan2
- MYO1F | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 60/157 reads (38%) | catalogued as rs754747494, COSV100596326, COSV100596670; called by muse, mutect2, varscan2
- MYO7A | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs373942326; called by muse, mutect2, varscan2
- MYOT | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV99524716; called by muse, mutect2, varscan2
- MZB1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs374843946; called by muse, mutect2, varscan2
- NAA16 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 294/828 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV101038216; called by muse, mutect2, varscan2
- NALCN | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs867467226, COSV51959339; called by muse, mutect2, varscan2
- NALCN | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs377716963, COSV51938533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NANOS2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.94); catalogued as COSV100379449; called by muse, varscan2
- NAP1L3 | c.515G>A p.S172N | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as COSV100220139; called by muse, mutect2, varscan2
- NAV2 | c.6744C>A p.H2248Q (on ENST00000396087 / NM_001244963.2; = p.H2189Q on NM_145117.5) | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100216037; called by muse, mutect2, varscan2
- NBEAL1 | c.5426G>A p.R1809H | Missense Mutation (SNP) | VAF 132/400 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs372102920; called by muse, varscan2
- NCAPD2 | c.2508del p.F837Sfs*36 | Frame Shift Del (DEL) | VAF 136/320 reads (43%) | catalogued as rs772347389; called by mutect2, pindel, varscan2
- NCOA3 | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV100507081, COSV59066442; called by muse, mutect2, varscan2
- NCSTN | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 162/453 reads (36%) | catalogued as rs771414318, COSV99666682; called by muse, mutect2, varscan2
- NDST2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs748197644, COSV100013608; called by muse, mutect2, varscan2
- NDUFAF4 | c.386T>C p.F129S | Missense Mutation (SNP) | VAF 130/348 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100293992; called by muse, mutect2, varscan2
- NECAB2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs748924576, COSV100533818; called by muse, mutect2, varscan2
- NECTIN1 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as rs759345182, COSV99871744; called by muse, mutect2, varscan2
- NEXMIF | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 539/842 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV99279516; called by muse, mutect2, varscan2
- NFATC3 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 114/280 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as COSV100284834; called by muse, mutect2, varscan2
- NFIA | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 113/381 reads (30%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.992); catalogued as rs1252714201, COSV100963174; called by muse, mutect2, varscan2
- NFIC | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as rs771779620, COSV100545038; called by muse, mutect2, varscan2
- NIBAN2 | c.421+2T>C p.X141_splice | Splice Site (SNP) | VAF 28/115 reads (24%) | catalogued as COSV100964845; called by muse, mutect2, varscan2
- NID1 | c.3121A>G p.N1041D | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.102); catalogued as COSV99936929; called by muse, mutect2, varscan2
- NINJ1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.532); catalogued as rs755546683, COSV100966592; called by muse, mutect2, varscan2
- NKX3-1 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs753524833, COSV66513039; called by muse, mutect2, varscan2
- NME7 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 149/441 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs755169173, COSV100890869; called by muse, mutect2, varscan2
- NMT1 | c.188del p.K63Rfs*17 | Frame Shift Del (DEL) | VAF 48/180 reads (27%) | catalogued as rs1567865446; called by mutect2, pindel, varscan2
- NOC3L | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 176/475 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs763109129, COSV64929629; called by muse, mutect2, varscan2
- NOD1 | c.2348G>A p.C783Y | Missense Mutation (SNP) | VAF 128/373 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs773339280, COSV99767763; called by muse, mutect2, varscan2
- NOD1 | c.276A>C p.Q92H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99767764; called by muse, mutect2, varscan2
- NOS1AP | c.700A>G p.S234G | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100722800; called by muse, mutect2, varscan2
- NOS2 | c.2827G>A p.V943I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs753799387, COSV100569471; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOSIP | c.394A>C p.K132Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.154); catalogued as COSV100182103; called by muse, mutect2, varscan2
- NOTCH2 | c.5537A>G p.D1846G | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.161); catalogued as COSV99862632; called by muse, mutect2, varscan2
- NPAS3 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100385944; called by muse, varscan2
- NPAS4 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); catalogued as rs777027579, COSV60650844; called by muse, mutect2, varscan2
- NPHP3 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 221/677 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as COSV100446593; called by muse, mutect2, varscan2
- NRDC | c.1847T>A p.I616N | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100703049; called by muse, mutect2
- NRXN1 | c.1939T>G p.L647V | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV58477011; called by muse, mutect2, varscan2
- NSD2 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100372804; called by muse, mutect2, varscan2
- NTHL1 | c.788G>A p.R263H (on ENST00000219066; = p.R255H on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756036462, COSV99526089; called by muse, mutect2, varscan2
- NTRK3 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 39/148 reads (26%) | catalogued as rs1419472052, COSV62305329, COSV62313231; called by muse, mutect2, varscan2
- NUAK1 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs941006183, COSV54605720; called by muse, mutect2, varscan2
- NUFIP1 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 144/465 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371806496; called by muse, mutect2, varscan2
- NUP160 | c.4096C>T p.H1366Y | Missense Mutation (SNP) | VAF 151/415 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1322460209, COSV101021258; called by muse, mutect2, varscan2
- OGFOD3 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746705584, COSV57340805; called by muse, mutect2, varscan2
- OLFM1 | c.180G>A p.W60* (on ENST00000371793 / NM_001282611.2; = p.W42* on NM_006334.4) | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99423071; called by muse, mutect2, varscan2
- OPRM1 | c.1075A>G p.N359D | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100000305; called by muse, mutect2, varscan2
- OR10A2 | c.721T>C p.S241P | Missense Mutation (SNP) | VAF 138/376 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs768034593, COSV100224924; called by muse, mutect2, varscan2
- OR13C3 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 76/344 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101053248; called by muse, mutect2, varscan2
- OR1E1 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV100491877; called by muse, mutect2, varscan2
- OR2A42 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs778163355; called by mutect2, varscan2
- OR2L3 | c.379T>C p.F127L | Missense Mutation (SNP) | VAF 342/858 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.529); catalogued as COSV100741905; called by muse, mutect2, varscan2
- OR2M3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 114/321 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs138010167; called by muse, mutect2, varscan2
- OR2M7 | c.742G>C p.V248L | Missense Mutation (SNP) | VAF 96/265 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100522407, COSV58738519; called by muse, mutect2, varscan2
- OR51V1 | c.136T>C p.C46R | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV100343173; called by muse, mutect2, varscan2
- OR52J3 | c.933del p.K311Nfs*? | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs1254479213; called by mutect2, pindel, varscan2
- OR52K1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 173/547 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV100297564; called by muse, mutect2, varscan2
- OR56A1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100360387; called by muse, mutect2, varscan2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 66/174 reads (38%) | catalogued as rs747074822; called by mutect2, varscan2
- OR6K2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs752799224, COSV100656655, COSV62744312; called by muse, mutect2, varscan2
- OR6K3 | c.554G>A p.C185Y (on ENST00000368146; = p.C169Y on NM_001005327.2) | Missense Mutation (SNP) | VAF 119/296 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322601769, COSV100933826; called by muse, mutect2, varscan2
- OR8H2 | c.528C>A p.H176Q | Missense Mutation (SNP) | VAF 22/508 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100542128; called by muse, mutect2
- OR8K1 | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.275); catalogued as rs1350964624, COSV99687048; called by muse, mutect2, varscan2
- OS9 | c.950A>T p.E317V | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV99232490; called by muse, mutect2, varscan2
- OSBPL3 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as rs150182562, COSV100513649; called by muse, mutect2, varscan2
- OSCP1 | c.895T>A p.L299M (on ENST00000356637 / NM_001330493.1; = p.L289M on NM_145047.5) | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99347000; called by muse, mutect2, varscan2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 180/638 reads (28%) | catalogued as rs762315064; called by mutect2, pindel, varscan2
- OTOL1 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1163712798, COSV100019728; called by muse, varscan2
- OXCT2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59594352; called by muse, mutect2, varscan2
- P2RX2 | c.661G>A p.G221R (on ENST00000343948 / NM_170683.4; = p.G149R on NM_012226.5) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV57683158; called by muse, mutect2, varscan2
- PABPC5 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100442091; called by muse, mutect2, varscan2
- PACS2 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs782813839, COSV100330587; called by muse, mutect2, varscan2
- PADI6 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs749241013, COSV100639888; called by muse, mutect2, varscan2
- PAIP1 | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100166482, COSV59085936; called by muse, varscan2
- PAK1 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 249/784 reads (32%) | catalogued as rs201726311, COSV53695751; called by muse, mutect2, varscan2
- PARD3 | c.2203C>A p.L735I | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.269); catalogued as COSV60756995; called by muse, mutect2
- PARD3 | c.123T>C p.D41= | Splice Region (SNP) | VAF 350/1040 reads (34%) | catalogued as COSV100400159; called by muse, mutect2, varscan2
- PARD3B | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100592060; called by muse, mutect2, varscan2
- PARP6 | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99535739; called by muse, mutect2, varscan2
- PASK | c.962G>C p.S321T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.138); catalogued as COSV52153143, COSV99298585; called by muse, mutect2, varscan2
- PASK | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372015883, COSV99298588; called by muse, mutect2, varscan2
- PCDH17 | c.3190C>A p.L1064M | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.445); catalogued as COSV100931407; called by muse, mutect2, varscan2
- PCDH19 | c.3191C>A p.P1064H (on ENST00000373034 / NM_001184880.2; = p.P1016H on NM_020766.3) | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99718948; called by muse, mutect2
- PCDHA9 | c.94C>A p.H32N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV100968973; called by muse, varscan2
- PCDHB1 | c.2023C>A p.Q675K | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100128011; called by muse, mutect2, varscan2
- PCDHB13 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99506670; called by muse, mutect2, varscan2
- PCDHGA4 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV53894994; called by muse, mutect2, varscan2
- PCGF3 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as rs757796778, COSV62860309; called by mutect2, varscan2
- PCID2 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.044); catalogued as rs760400800, COSV99872316; called by muse, mutect2
- PCM1 | c.778del p.I260Sfs*14 | Frame Shift Del (DEL) | VAF 44/138 reads (32%) | catalogued as COSV61518405; called by mutect2, pindel, varscan2
- PCNT | c.7316C>T p.T2439M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.272); catalogued as rs141561546; called by mutect2, varscan2
- PCNX3 | c.3533C>T p.A1178V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.622); catalogued as rs1475468415, COSV100855996; called by muse, mutect2, varscan2
- PDCL3 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99959426; called by muse, mutect2, varscan2
- PEG3 | c.3668C>T p.S1223L | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs777391933, COSV55630395; called by muse, mutect2, varscan2
- PEG3 | c.2464G>T p.G822W | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV99687088; called by muse, mutect2, varscan2
- PEX12 | c.352A>G p.M118V | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs773708442, COSV99862018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHB | c.347A>C p.E116A | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100303095; called by muse, mutect2, varscan2
- PHGDH | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as COSV101025011; called by muse, mutect2, varscan2
- PHTF1 | c.1637dup p.M547Hfs*10 | Frame Shift Ins (INS) | VAF 140/448 reads (31%) | catalogued as rs750248180; called by mutect2, varscan2
- PIK3C3 | c.127A>C p.M43L | Missense Mutation (SNP) | VAF 151/693 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100010229; called by muse, mutect2, varscan2
- PIP5KL1 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100304780; called by muse, mutect2, varscan2
- PIWIL1 | c.1122del p.T375Hfs*18 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs1298170486, COSV55345426; called by mutect2, pindel, varscan2
- PIWIL1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 173/346 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs1225500017, COSV55346646, COSV99807047; called by muse, mutect2, varscan2
- PKDCC | c.1270T>A p.C424S | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99684632; called by muse, mutect2, varscan2
- PKHD1 | c.8208G>A p.W2736* | Nonsense Mutation (SNP) | VAF 19/414 reads (5%) | catalogued as COSV100580946; called by muse, mutect2
- PKN3 | c.2036_2038del p.K679del | In Frame Del (DEL) | VAF 18/128 reads (14%) | catalogued as rs747170999; called by pindel, varscan2
- PKN3 | c.2245C>T p.L749F | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52578572; called by muse, mutect2
- PKP4 | c.911C>A p.P304H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs1278740407, COSV101080138; called by muse, mutect2, varscan2
- PLA2G6 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.749); catalogued as rs369038599, CM166192, COSV99061469; called by muse, mutect2, varscan2
- PLA2R1 | c.182T>A p.L61Q | Missense Mutation (SNP) | VAF 79/232 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99322073; called by muse, mutect2, varscan2
- PLAA | c.565+2T>C p.X189_splice | Splice Site (SNP) | VAF 19/488 reads (4%) | catalogued as COSV101263480; called by muse, mutect2
- PLAGL1 | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99394114; called by muse, mutect2, varscan2
- PLEKHA2 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1430973973, COSV56760686; called by muse, mutect2, varscan2
- PLEKHG4B | c.1460C>T p.P487L (on ENST00000283426; = p.P843L on NM_052909.5) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.107); catalogued as rs149715797; called by muse, varscan2
- PLEKHO1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.662); catalogued as rs782430585, COSV50310735; called by muse, mutect2, varscan2
- PLIN1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756661343, COSV55584272; called by muse, mutect2, varscan2
- PLPP7 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760054266, COSV64841453; called by muse, varscan2
- PLXNB1 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99602193; called by muse, mutect2, varscan2
- PNPLA1 | c.1421C>A p.A474D (on ENST00000394571 / NM_001374623.1; = p.A379D on NM_173676.2) | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); catalogued as COSV100462609; called by muse, mutect2, varscan2
- POC1B | c.511T>G p.W171G | Missense Mutation (SNP) | VAF 378/733 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100544031; called by muse, mutect2, varscan2
- PODXL2 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs749040344, COSV61065348; called by muse, mutect2, varscan2
- PODXL2 | c.629G>C p.S210T | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100686114; called by muse, mutect2, varscan2
- POF1B | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 690/1204 reads (57%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.996); catalogued as COSV53137592, COSV99425944; called by muse, mutect2, varscan2
- POGLUT3 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 255/698 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100052483; called by muse, mutect2, varscan2
- POLR1A | c.3452G>A p.R1151H | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1029249129, COSV55696721; called by muse, mutect2, varscan2
- POLR1B | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 107/382 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99637022; called by muse, mutect2, varscan2
- POLR1B | c.2942G>A p.S981N | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99637024; called by muse, mutect2, varscan2
- POTEF | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.97); catalogued as COSV100664540; called by muse, mutect2
- POTEH | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV100624656; called by muse, varscan2
- POU3F4 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1437688252, COSV100937152; called by muse, mutect2, varscan2
- POU4F1 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1243570651, COSV65884264; called by muse, mutect2, varscan2
- POU4F2 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.37); catalogued as rs766646381, COSV55585975; called by muse, mutect2
- PPARGC1A | c.1027A>G p.N343D | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.15); catalogued as COSV99337165; called by muse, mutect2, varscan2
- PPFIA2 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 212/901 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100331551; called by muse, mutect2, varscan2
- PPP1R3D | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.085); catalogued as rs1334778776, COSV62564762; called by muse, mutect2
- PRPF40A | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.584); catalogued as COSV100582602; called by muse, mutect2, varscan2
- PRPF6 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as rs1344492269, COSV99411226; called by muse, mutect2, varscan2
- PRRC2B | c.6023G>A p.S2008N | Missense Mutation (SNP) | VAF 141/296 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV57645918; called by muse, mutect2, varscan2
- PRXL2A | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs770934321, COSV100939745; called by muse, mutect2, varscan2
- PSD | c.2197A>G p.K733E | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV50054594; called by muse, varscan2
- PSG8 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 156/431 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs200167716, COSV100126217; called by muse, mutect2, varscan2
- PSKH1 | c.1028del p.R343Lfs*2 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | catalogued as COSV52122432, COSV52122793; called by mutect2, pindel, varscan2
- PTPN12 | c.2119C>T p.R707* | Nonsense Mutation (SNP) | VAF 47/134 reads (35%) | catalogued as COSV50356854; called by muse, mutect2, varscan2
- PTPN14 | c.1707del p.Y570Tfs*29 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | catalogued as COSV65287671; called by mutect2, pindel, varscan2
- PTPN9 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV60725584; called by muse, mutect2, varscan2
- PTPRC | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 314/890 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as COSV61420058; called by muse, mutect2, varscan2
- PTPRG | c.2811G>T p.R937S | Missense Mutation (SNP) | VAF 163/541 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99872676; called by muse, mutect2, varscan2
- PTPRH | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV99670647; called by muse, mutect2, varscan2
- PTPRM | c.1928A>G p.Y643C | Missense Mutation (SNP) | VAF 110/437 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100154638; called by muse, mutect2, varscan2
- PTPRN2 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1349980584, COSV101233568; called by muse, mutect2, varscan2
- PTPRT | c.3499G>A p.D1167N | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100624937; called by muse, mutect2, varscan2
- PTPRT | c.3196G>A p.V1066I | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1358914349, COSV61986580; called by muse, mutect2, varscan2
- PUM1 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 60/183 reads (33%) | catalogued as COSV99927448; called by muse, mutect2, varscan2
- PXDN | c.2308G>A p.V770M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV99412177; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 32/134 reads (24%) | catalogued as rs754588466; called by mutect2, varscan2
- RAB28 | c.433_436del p.L145Gfs*37 | Frame Shift Del (DEL) | VAF 105/353 reads (30%) | catalogued as rs1322389318; called by mutect2, pindel, varscan2
- RAB3C | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99276663; called by muse, mutect2, varscan2
- RABGGTB | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 139/414 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as rs750012267, COSV60638928; called by muse, mutect2, varscan2
- RAI1 | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs776854795, COSV55391537; called by muse, mutect2, varscan2
- RAI14 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV99461726; called by muse, mutect2, varscan2
- RALGAPA1 | c.5342G>T p.R1781M | Missense Mutation (SNP) | VAF 115/346 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV51891301; called by muse, mutect2, varscan2
- RALGAPA2 | c.4189A>G p.I1397V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777380984, COSV52505365; called by mutect2, varscan2
- RAMP3 | c.290A>G p.H97R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99642152; called by muse, mutect2, varscan2
- RASA3 | c.1913A>C p.E638A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.542); catalogued as rs753088536, COSV100479702; called by muse, mutect2, varscan2
- RBFOX1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1174108648, COSV100299392; called by muse, mutect2, varscan2
- RBM33 | c.1121del p.P374Rfs*4 | Frame Shift Del (DEL) | VAF 32/126 reads (25%) | catalogued as COSV56630719; called by mutect2, pindel, varscan2
- RBM6 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 90/314 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs139195645; called by muse, varscan2
- RCC1L | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 295/877 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs1306616077; called by muse, mutect2, varscan2
- RCC2 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780378675, COSV100965106; called by muse, mutect2, varscan2
- REC8 | c.827dup p.E277Gfs*85 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs766853930; called by mutect2, varscan2
- REEP2 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755450430, COSV99649495; called by muse, mutect2, varscan2
- RERE | c.4046G>A p.R1349Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs755080487, COSV100555330; called by muse, mutect2, varscan2
- RET | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs137855422, COSV60694204; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RETREG3 | c.1073A>G p.Y358C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99518706; called by muse, mutect2, varscan2
- REV3L | c.5654del p.P1885Qfs*45 | Frame Shift Del (DEL) | VAF 92/307 reads (30%) | catalogued as COSV100725173; called by mutect2, pindel, varscan2
- RGS9 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as rs759032207, COSV99287107; called by muse, mutect2, varscan2
- RHOT1 | c.1236del p.K412Nfs*12 | Frame Shift Del (DEL) | VAF 157/518 reads (30%) | catalogued as rs1268439837; called by mutect2, pindel, varscan2
- RIMKLA | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 52/322 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs746132310, COSV101290549; called by muse, mutect2, varscan2
- RIMS1 | c.54del p.M19Cfs*7 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs1378143186; called by mutect2, pindel, varscan2
- RIPK4 | c.1565del p.P522Rfs*90 (on ENST00000352483; = p.P474Rfs*90 on NM_020639.3) | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as COSV60186557; called by mutect2, pindel, varscan2
- RMND5B | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs774372243, COSV100523171; called by muse, varscan2
- RNASE7 | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 97/329 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as COSV100069637; called by muse, mutect2, varscan2
- RNF145 | c.1534C>T p.R512C (on ENST00000424310 / NM_001199383.2; = p.R540C on NM_144726.2) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749109573, COSV99193221; called by muse, mutect2, varscan2
- RNF145 | c.1139T>C p.F380S (on ENST00000424310 / NM_001199383.2; = p.F408S on NM_144726.2) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99193224; called by muse, mutect2, varscan2
- RNF145 | c.676G>A p.V226I (on ENST00000424310 / NM_001199383.2; = p.V254I on NM_144726.2) | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.58); catalogued as COSV99193225; called by muse, varscan2
- RNF168 | c.181T>C p.W61R | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100534818; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs755128667, COSV68457540; called by pindel, varscan2
- RNGTT | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 296/752 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99665483; called by muse, mutect2, varscan2
- RNPC3 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV100796164; called by muse, mutect2, varscan2
- ROR2 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs1473967816, COSV100995443; called by muse, mutect2, varscan2
- RORB | c.1204G>T p.A402S (on ENST00000396204 / NM_001365023.1; = p.A391S on NM_006914.4) | Missense Mutation (SNP) | VAF 221/427 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.263); catalogued as COSV100974265, COSV65338558; called by muse, mutect2, varscan2
- ROS1 | c.3418G>A p.A1140T | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100876356; called by muse, mutect2, varscan2
- RP9 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 258/828 reads (31%) | catalogued as COSV51806198; called by muse, mutect2, varscan2
- RPE65 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 105/312 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99253539; called by muse, mutect2, varscan2
- RPL3L | c.341G>A p.C114Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs1567311979, COSV99237976; called by muse, mutect2, varscan2
- RSAD1 | c.1230G>T p.W410C | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV99364103; called by muse, mutect2, varscan2
- RSPH1 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769151189, COSV52321218; called by muse, mutect2, varscan2
- RSRC1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as rs557840086, COSV99905321; called by muse, mutect2, varscan2
- RTCA | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as rs1172158150, COSV99559503; called by muse, mutect2, varscan2
- RUNDC3A | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs754541765, COSV56588586; called by muse, mutect2, varscan2
- RUVBL1 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1319441844, COSV100494027; called by muse, varscan2
- RYR2 | c.5279G>A p.R1760Q | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.111); catalogued as rs765106198, COSV100767606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.13054A>G p.K4352E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as COSV100767607; called by muse, mutect2, varscan2
- RYR3 | c.6710del p.G2237Efs*56 (on ENST00000389232; = p.G2237Efs*57 on NM_001036.6) | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs751516213; called by mutect2, pindel, varscan2
815 further variants in this file (421 protein-altering or splice-affecting, 360 silent, 34 other) are not listed here.
